Somatic mutation profile of tumor specimen TCGA-B5-A3FD-01A (aliquot TCGA-B5-A3FD-01A-11D-A19Y-09) from TCGA case TCGA-B5-A3FD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 70.7 years (25,813 days).
Specimen TCGA-B5-A3FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59875d1c-4705-47a0-b42a-e1d1b1c135d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A3FD-10A (Blood Derived Normal), aliquot TCGA-B5-A3FD-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cef95ff-fed5-4f05-a7cd-3ae33d03b722

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 17, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 32/71 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 24/29 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP35 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 38/60 reads (63%) | catalogued as COSV68328962; called by muse, mutect2, varscan2
- ATF7IP2 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs75627261, COSV61092139, COSV61092592; called by muse, mutect2, varscan2
- ATP6V0D1 | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV99340965; called by muse, mutect2
- CLCA1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99321964; called by muse, mutect2, varscan2
- DDX43 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV100943914, COSV64813826; called by muse, mutect2, varscan2
- EIF2S3 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV99450711; called by muse, mutect2
- FBXW10 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs139724959; called by muse, mutect2, varscan2
- FOXN1 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99881014; called by muse, mutect2, varscan2
- FOXO1 | c.1472T>A p.V491D | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV101091814; called by muse, mutect2, varscan2
- FTHL17 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV63267710; called by muse, mutect2, varscan2
- KIF20B | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs145716217; called by muse, mutect2, varscan2
- KMT2C | c.7163G>A p.R2388H | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100072263, COSV51483454; called by muse, mutect2, varscan2
- LMOD2 | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV101505415; called by muse, mutect2, varscan2
- LRP1B | c.6150+1G>T p.X2050_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV67214573; called by muse, mutect2
- LRP5 | c.3638C>T p.S1213L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745554938, COSV99591526; called by muse, mutect2, varscan2
- LRRC8B | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756518618, COSV100446460; called by muse, mutect2, varscan2
- MAP4K4 | c.2312C>T p.S771L (on ENST00000347699 / NM_001242559.2; = p.S689L on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV100153543; called by muse, mutect2, varscan2
- MPHOSPH8 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.449); catalogued as rs867446648, COSV100824984; called by muse, mutect2, varscan2
- MRPL2 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV52436145, COSV99431450; called by muse, mutect2, varscan2
- MYOM1 | c.3410C>T p.T1137I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs763744233, COSV99865556; called by muse, mutect2, varscan2
- OAS2 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs141277168, COSV60804760; called by muse, mutect2, varscan2
- PARP14 | c.3265G>A p.V1089M | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101506235; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs760886735, COSV99460918; called by muse, mutect2, varscan2
- PRKAR1A | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100675077; called by muse, mutect2, varscan2
- PSPC1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs867658733, COSV100142096; called by muse, mutect2, varscan2
- SRRM4 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs780766753, COSV99937872; called by muse, mutect2, varscan2
- TAF1 | c.2545C>T p.R849C (on ENST00000373790 / NM_138923.4; = p.R870C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52109893; called by muse, mutect2, varscan2
- TALDO1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100032481; called by muse, mutect2, varscan2
- TTN | c.102010C>T p.L34004F (on ENST00000591111; = p.L26580F on NM_003319.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | PolyPhen possibly damaging (0.859); catalogued as COSV100597438; called by muse, mutect2, varscan2
- UPF3B | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99351996; called by muse, mutect2, varscan2
- ZNF180 | c.897A>T p.K299N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.287); catalogued as COSV55420769, COSV99659631; called by muse, mutect2, varscan2
- ZNF202 | c.1280G>A p.C427Y | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100278933, COSV100278993; called by muse, mutect2, varscan2
- FCER2 | c.264_265dup p.S89Ffs*15 | Frame Shift Ins (INS) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- PTEN | c.604_622del p.T202Afs*13 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, varscan2
- SHANK2 | c.2681_2682del p.V894Afs*27 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by pindel, varscan2
- TUSC3 | c.807dup p.H270Sfs*31 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- CYP4F12 | c.897T>A p.I299= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV100215650; called by muse, mutect2, varscan2
- DCAF12L2 | c.69G>A p.S23= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100758478; called by muse, mutect2, varscan2
- EIF4G3 | c.4491C>T p.L1497= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV51680509, COSV99943412; called by muse, mutect2, varscan2
- FAM20B | c.553T>C p.L185= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV99762150; called by muse, mutect2, varscan2
- ITGA2 | c.2214C>A p.P738= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV56861303, COSV99670329; called by muse, mutect2, varscan2
- LIN9 | c.1002C>G p.T334= (on ENST00000366808 / NM_001270410.2; = p.T279= on NM_173083.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100067085; called by muse, mutect2, varscan2
- MROH2B | c.2571C>T p.H857= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV101270546; called by muse, mutect2, varscan2
- NAP1L2 | c.84G>C p.G28= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100999185; called by muse, mutect2, varscan2
- OR2L3 | c.552G>T p.V184= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100741922; called by muse, mutect2, varscan2
- OR2L8 | c.552G>T p.V184= | Silent (SNP) | VAF 28/267 reads (10%) | catalogued as COSV100594053; called by muse, mutect2, varscan2
- RECQL4 | c.3132C>T p.T1044= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs373238823; ClinVar: likely benign; called by muse, mutect2, varscan2
- RGS11 | c.735C>T p.S245= (on ENST00000397770 / NM_183337.3; = p.S224= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs749289973, COSV51453666; called by muse, mutect2, varscan2
- SLC1A6 | c.465C>T p.P155= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs760995484, COSV55674010; called by muse, mutect2, varscan2
- STOX1 | c.2898C>T p.V966= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as rs375370325; called by muse, mutect2, varscan2
- TMEM131 | c.3828G>A p.A1276= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs771911652, COSV99490034; called by muse, mutect2, varscan2
- TMEM164 | c.72T>C p.N24= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV99911415; called by muse, mutect2, varscan2
- TRPS1 | c.2439G>A p.L813= (on ENST00000220888 / NM_001330599.2; = p.L826= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV55232520, COSV99628808; called by muse, mutect2, varscan2
- AFDN | chr6:167826061 G>A | 5'Flank (SNP) | VAF 106/255 reads (42%) | catalogued as rs774725716; called by muse, mutect2, varscan2
- FARP1 | c.2275-980G>A | Intron (SNP) | VAF 34/81 reads (42%) | catalogued as rs747423163, COSV100129769; called by muse, mutect2, varscan2
